Somatic mutation profile of tumor specimen TCGA-GN-A26C-01A (aliquot TCGA-GN-A26C-01A-11D-A19A-08) from TCGA case TCGA-GN-A26C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.8 years (28,427 days).
Specimen TCGA-GN-A26C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a7949d1-1049-4d34-bbd7-e4317e1296ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A26C-10A (Blood Derived Normal), aliquot TCGA-GN-A26C-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a80f9789-bc1e-4f36-ab23-b11f5f7f78b0

The open-access MAF lists 2,060 somatic variants for this specimen: 1,309 protein-altering or splice-affecting, 699 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,199, Silent 699, Nonsense Mutation 69, Intron 22, Splice Site 17, Splice Region 15, RNA 14, Frame Shift Del 8, 3'Flank 5, 3'UTR 4, 5'Flank 4, 5'UTR 3.

Variants (750 of 2,060; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs730880403, COSV51757334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CRNKL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057519885, COSV55618331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs763413735, COSV59534728; called by mutect2, varscan2
- NF1 | c.1811T>A p.L604* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs1555613427, CM071892, COSV62221194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP1 | c.1036C>T p.R346* (on ENST00000393272 / NM_207181.4; = p.R347* on NM_000272.5) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs765263671, CM080456, COSV57206565; ClinVar: pathogenic; called by mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 36/173 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by muse, mutect2, varscan2
- TCF20 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59491013; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 51/107 reads (48%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TRPV6 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1281361203, COSV63892531; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.234+2T>G p.X78_splice | Splice Site (SNP) | VAF 23/159 reads (14%) | catalogued as COSV50977139, COSV51021042; called by muse, varscan2
- A4GALT | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1317286745, COSV50746244; called by muse, varscan2
- AASS | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62791723; called by muse, mutect2, varscan2
- ABCA7 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54029973; called by muse, mutect2, varscan2
- ABCA8 | c.2567C>T p.S856F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV52198524, COSV52211859; called by muse, mutect2, varscan2
- ABCC3 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV53329052; called by mutect2, varscan2
- ABCC9 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53985597; called by muse, mutect2, varscan2
- ABCD2 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV58055115; called by muse, mutect2, varscan2
- ABCG2 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52947503; called by mutect2, varscan2
- ABL2 | c.1811C>T p.S604F (on ENST00000502732 / NM_007314.4; = p.S589F on NM_005158.5) | Missense Mutation (SNP) | VAF 144/431 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV61020480; called by muse, mutect2, varscan2
- ABLIM3 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58648532; called by muse, mutect2, varscan2
- AC097636.1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1395619790, COSV101469699, COSV71309661; called by muse, mutect2, varscan2
- AC098582.1 | c.2020A>C p.N674H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV52024555; called by muse, mutect2, varscan2
- ACACB | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as rs759694366, COSV58145648; called by mutect2, varscan2
- ACAN | c.4655G>A p.G1552E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.219); catalogued as COSV61369171; called by muse, mutect2, varscan2
- ACCS | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55460254; called by muse, varscan2
- ACE2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53027598; called by mutect2, varscan2
- ACIN1 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52982110; called by muse, mutect2, varscan2
- ACKR1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 122/422 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as COSV63674515; called by mutect2, varscan2
- ACKR3 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56020781; called by muse, varscan2
- ACOT11 | c.589A>T p.N197Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59351847; called by muse, varscan2
- ACSL5 | c.167G>A p.R56Q (on ENST00000354273; = p.R112Q on NM_016234.3) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs761769732, COSV61133426; called by mutect2, varscan2
- ACSM4 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV68069329; called by muse, mutect2, varscan2
- ACTG2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.423); catalogued as COSV61829644; called by mutect2, varscan2
- ACTRT2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV65760475; called by muse, mutect2, varscan2
- ADAD2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51895222; called by mutect2, varscan2
- ADAM12 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64114516; called by muse, mutect2, varscan2
- ADAM18 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55854999; called by mutect2, varscan2
- ADAM7 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370002414, COSV51538649; called by muse, mutect2, varscan2
- ADCY10 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.236); catalogued as COSV63244828; called by mutect2, varscan2
- ADCY5 | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59194168; called by muse, mutect2, varscan2
- ADD2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs782227971, COSV100035853, COSV52459390, COSV52462329; called by muse, mutect2, varscan2
- ADGRB2 | c.4586C>T p.P1529L (on ENST00000373658 / NM_001364857.2; = p.P1528L on NM_001294335.2) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV57078720; called by muse, mutect2
- ADGRB2 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775608837, COSV57078734; called by mutect2, varscan2
- ADGRE2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59696263; called by muse, mutect2, varscan2
- ADGRE3 | c.1517G>A p.W506* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs1263522476; called by muse, mutect2
- ADGRL2 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54688710, COSV99591799; called by mutect2, varscan2
- ADGRL2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs757781676, COSV54683574, COSV54689423; called by mutect2, varscan2
- ADGRV1 | c.9757G>A p.D3253N | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67995137; called by muse, mutect2, varscan2
- ADGRV1 | c.11107C>T p.P3703S | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs267600730, COSV67979814; called by muse, mutect2, varscan2
- ADPRS | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.136); catalogued as COSV57443448; called by muse, mutect2, varscan2
- AFF3 | c.2934T>A p.D978E | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57872918; called by muse, mutect2, varscan2
- AFF4 | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as rs1340864663; called by muse, mutect2, varscan2
- AGBL1 | c.1607G>A p.W536* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV66872374; called by muse, mutect2, varscan2
- AGTR2 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV64156612, COSV64157044; called by muse, mutect2, varscan2
- AHNAK2 | c.15415G>A p.G5139R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.059); catalogued as rs368740292; called by muse, mutect2, varscan2
- AIPL1 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 67/195 reads (34%) | catalogued as COSV51508945; called by muse, mutect2, varscan2
- AKR1C3 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs782497370, COSV65911184; called by mutect2, varscan2
- AKR1C3 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV65911194; called by muse, mutect2, varscan2
- AKR7A3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64389743; called by muse, mutect2, varscan2
- AL121899.2 | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454133853, COSV67352335; called by muse, mutect2
- ALDH18A1 | c.1933C>T p.H645Y | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV64662432; called by muse, mutect2, varscan2
- ALDH6A1 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63246578; called by mutect2, varscan2
- ALPK2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV64496570, COSV64497004; called by muse, mutect2, varscan2
- ALPK3 | c.4340C>T p.S1447F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV51939610; called by muse, mutect2, varscan2
- AMER3 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as rs267598875, COSV58469978; called by muse, mutect2, varscan2
- AMPD1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554825859, COSV62418929; called by muse, mutect2, varscan2
- ANGPT1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV52456559; called by muse, mutect2, varscan2
- ANGPTL3 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52020897; called by mutect2, varscan2
- ANK1 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs911722560, COSV55891781; called by muse, mutect2, varscan2
- ANKRD2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs776638651; called by mutect2, varscan2
- ANKRD30A | c.931G>A p.E311K (on ENST00000611781; = p.E255K on NM_052997.2) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.292); catalogued as COSV64620881; called by muse, mutect2, varscan2
- ANKRD30A | c.1405C>T p.P469S (on ENST00000611781; = p.P413S on NM_052997.2) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.441); catalogued as COSV64620894; called by muse, varscan2
- ANO3 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV56808188; called by mutect2, varscan2
- ANO4 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54586601; called by muse, mutect2, varscan2
- ANPEP | c.1691A>G p.E564G | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs546399148, COSV55595108; called by muse, mutect2, varscan2
- ANTXR1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV58021750; called by mutect2, varscan2
- ANXA10 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs752116805, COSV63740395; called by muse, mutect2, varscan2
- AOC1 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62870791; called by muse, mutect2, varscan2
- AOC2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 122/291 reads (42%) | catalogued as rs372937888; called by muse, mutect2, varscan2
- APBB1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54980420; called by muse, mutect2
- APBB1IP | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV66130583; called by mutect2, varscan2
- APC | c.5273C>T p.S1758F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as COSV57380924; called by mutect2, varscan2
- APOB | c.10846C>T p.L3616F | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV51951728; called by muse, varscan2
- APOBR | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV60491076; called by muse, mutect2
- APOL5 | c.173A>T p.K58I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50768511; called by mutect2, varscan2
- APPL1 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041140473, COSV55703574; called by mutect2, varscan2
- ARHGAP26 | c.1757A>T p.K586M | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as COSV50841046; called by mutect2, varscan2
- ARHGAP32 | c.2070G>A p.M690I (on ENST00000310343 / NM_001378025.1; = p.M341I on NM_014715.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV59855537; called by muse, mutect2, varscan2
- ARHGEF5 | c.4750C>T p.R1584* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as rs750003677, COSV50209207, COSV99283095; called by mutect2, varscan2
- ARID2 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV57608056; called by mutect2, varscan2
- ARPP21 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV51807927; called by muse, mutect2, varscan2
- ASIC1 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57320173; called by muse, mutect2, varscan2
- ASTL | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV60905404; called by muse, mutect2, varscan2
- ASTN1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56084562; called by muse, mutect2, varscan2
- ATP10A | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604143, COSV63523995; called by muse, varscan2
- ATP1A1 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55194236; called by muse, mutect2, varscan2
- ATP2A3 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV59235117; called by muse, mutect2, varscan2
- ATP8A2 | c.2007G>A p.K669= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as rs1235868506, COSV54976196; called by muse, mutect2, varscan2
- ATP8B1 | c.1303A>G p.K435E | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.989); catalogued as COSV52180165; called by muse, mutect2, varscan2
- ATP9A | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs767492582, COSV58764411; called by mutect2, varscan2
- ATRN | c.3152G>A p.S1051N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs1202211308, COSV53534251; called by muse, mutect2, varscan2
- ATXN2L | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.497); catalogued as COSV57375233; called by muse, mutect2, varscan2
- ATXN3L | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV66076235; called by muse, mutect2, varscan2
- ATXN7 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV55751183; called by muse, varscan2
- B4GALNT2 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489404226, COSV55928231; called by muse, mutect2, varscan2
- BAG3 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs752722473, COSV104426906, COSV64842662; ClinVar: uncertain significance; called by mutect2, varscan2
- BCAM | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 113/317 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267255362, COSV54304836; called by muse, mutect2, varscan2
- BCAS3 | c.402T>A p.F134L | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV66782036; called by muse, mutect2, varscan2
- BCO1 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1222272747, COSV50733820; called by muse, mutect2, varscan2
- BDKRB2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV60016859; called by muse, mutect2, varscan2
- BDNF | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.437); catalogued as COSV59238351; called by muse, varscan2
- BEND2 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV66215638, COSV66217241; called by muse, mutect2, varscan2
- BEND3 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.348); catalogued as COSV64682268; called by muse, mutect2, varscan2
- BEST3 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58305558; called by mutect2, varscan2
- BLVRA | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV55514092; called by muse, mutect2
- BMP6 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs1319282365, COSV51672259; called by muse, mutect2, varscan2
- BNC1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.24); catalogued as COSV61759131; called by mutect2, varscan2
- BROX | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs866989832, COSV61799953; called by muse, mutect2
- BSN | c.9644C>T p.P3215L | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV56527123, COSV99608412; called by muse, mutect2, varscan2
- BTBD11 | c.1933C>T p.H645Y (on ENST00000280758 / NM_001018072.2; = p.H182Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV55037157; called by muse, mutect2, varscan2
- BTLA | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV57940636; called by muse, mutect2, varscan2
- BUB1 | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 58/221 reads (26%) | catalogued as COSV57067236; called by muse, mutect2, varscan2
- C10orf120 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV61492617; called by muse, mutect2, varscan2
- C11orf42 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60393189; called by mutect2, varscan2
- C19orf44 | c.-1-1G>A | Splice Site (SNP) | VAF 84/287 reads (29%) | catalogued as COSV54168870, COSV54172087; called by muse, mutect2, varscan2
- C19orf44 | c.1076-1G>A p.X359_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as rs768165306, COSV55614890; called by mutect2, varscan2
- C1QTNF4 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56784554; called by muse, mutect2
- C22orf31 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs866133658, COSV53311225; called by muse, mutect2, varscan2
- C22orf42 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.094); catalogued as COSV66076667; called by muse, mutect2, varscan2
- C3AR1 | c.656A>T p.N219I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV50824571; called by muse, mutect2, varscan2
- C6 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs867481239, COSV54706011; called by muse, mutect2, varscan2
- C7 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57480758; called by mutect2, varscan2
- C8A | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs755705114, COSV63483242; called by muse, mutect2, varscan2
- C8orf34 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV57402091, COSV57412799, COSV57415557; called by muse, mutect2, varscan2
- C9 | c.1664T>A p.F555Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1381204390, COSV54681496; called by mutect2, varscan2
- C9orf78 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as rs756733770, COSV65218081; called by mutect2, varscan2
- CA7 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV58157264; called by muse, mutect2, varscan2
- CACNA1A | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs867616569, COSV64198776; called by muse, mutect2, varscan2
- CACNA1C | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs786205746, COSV59742852; ClinVar: uncertain significance; called by mutect2, varscan2
- CACNA1S | c.4909G>A p.E1637K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.08); catalogued as COSV62943535; called by muse, varscan2
- CALR3 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54172081; called by muse, mutect2, varscan2
- CAMK2B | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51666389; called by muse, varscan2
- CAPN13 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54435331; called by muse, mutect2, varscan2
- CAPN5 | c.424C>T p.P142S (on ENST00000456580; = p.P102S on NM_004055.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53691228; called by muse, varscan2
- CAPN6 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60697169; called by muse, mutect2, varscan2
- CAPN6 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138687868, COSV100136595; called by muse, mutect2, varscan2
- CARD8 | c.457G>A p.E153K (on ENST00000651546 / NM_001184900.3; = p.E103K on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs774410020, COSV62875149; called by muse, mutect2, varscan2
- CARS1 | c.1894C>T p.H632Y | Missense Mutation (SNP) | VAF 46/340 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1407054593, COSV53460939, COSV53462834; called by muse, varscan2
- CASP10 | c.1357G>A p.E453K (on ENST00000272879 / NM_032974.5; = p.E410K on NM_001230.5) | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV53780541; called by muse, mutect2, varscan2
- CASP8AP2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as rs1352153007, COSV99387370; called by muse, mutect2, varscan2
- CASP8AP2 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV99387423; called by muse, mutect2, varscan2
- CASZ1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs754239516, COSV100682319, COSV59740877; called by muse, mutect2, varscan2
- CAT | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53813311; called by mutect2, varscan2
- CATSPERB | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1339189354, COSV56435103; called by mutect2, varscan2
- CATSPERB | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56435124; called by mutect2, varscan2
- CAVIN2 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as rs1485462312, COSV58423876; called by muse, mutect2, varscan2
- CAVIN4 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766006712, COSV100293427, COSV56868331; called by muse, mutect2, varscan2
- CBL | c.1101A>T p.Q367H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50663219; called by muse, mutect2, varscan2
- CBX8 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV53937615, COSV99485828; called by mutect2, varscan2
- CCDC146 | c.1404A>T p.E468D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53554453, COSV99592116; called by mutect2, varscan2
- CCDC18 | c.3241C>T p.R1081* (on ENST00000343253 / NM_001306076.1; = p.R1082* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 46/101 reads (46%) | catalogued as rs1162736223, COSV58141198; called by mutect2, varscan2
- CCDC69 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.52); catalogued as rs559088110, COSV62600716; called by muse, mutect2, varscan2
- CCDC83 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV54701443; called by muse, mutect2, varscan2
- CCDC89 | c.119A>T p.K40M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57034841; called by muse, mutect2, varscan2
- CCNA1 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV55222594, COSV55223907; called by muse, mutect2, varscan2
- CCNA1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55223922; called by mutect2, varscan2
- CCR3 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as COSV62465980; called by muse, mutect2, varscan2
- CCT8L2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63462861; called by muse, mutect2, varscan2
- CD163 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs755454282, COSV63137032; called by muse, mutect2, varscan2
- CD163L1 | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867081460, COSV58011299; called by muse, varscan2
- CD1B | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV63805183; called by muse, mutect2, varscan2
- CD207 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV69652707; called by muse, mutect2, varscan2
- CD80 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs376672655; called by mutect2, varscan2
- CDH13 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs1002354559, COSV51789667; called by mutect2, varscan2
- CDH23 | c.6553G>A p.E2185K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56489195; called by muse, mutect2, varscan2
- CDYL2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV73654949; called by mutect2, varscan2
- CEACAM19 | c.40A>C p.S14R | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV62552300; called by muse, mutect2, varscan2
- CEP135 | c.2929C>T p.L977F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV57262720; called by muse, mutect2, varscan2
- CEP162 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV57624569; called by mutect2, varscan2
- CEP250 | c.6145G>A p.E2049K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV61174270; called by mutect2, varscan2
- CEP76 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50866675, COSV50870340; called by muse, mutect2, varscan2
- CFAP47 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as COSV52891780, COSV99935511; called by muse, mutect2, varscan2
- CFAP52 | c.855G>A p.K285= | Splice Region (SNP) | VAF 37/95 reads (39%) | catalogued as rs1352129023, COSV55349357; called by muse, mutect2, varscan2
- CFHR2 | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs1274876698, COSV66380568; called by muse, mutect2, varscan2
- CFHR5 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV56828253; called by mutect2, varscan2
- CFTR | c.4351C>T p.P1451S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as COSV50079713; called by muse, mutect2, varscan2
- CHAT | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV60321463, COSV60332894; called by muse, mutect2, varscan2
- CHERP | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV52222981; called by muse, mutect2, varscan2
- CHGB | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV66761726; called by muse, mutect2, varscan2
- CHID1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs139154177; called by mutect2, varscan2
- CHPF | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60536687; called by muse, mutect2, varscan2
- CHRNB3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs1173756143, COSV51497847; called by muse, mutect2, varscan2
- CHST5 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60341566; called by muse, varscan2
- CIB2 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104386227, COSV51949516; called by muse, mutect2, varscan2
- CKAP2 | c.708G>A p.M236I (on ENST00000378037 / NM_001098525.2; = p.M235I on NM_018204.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs1282542579, COSV51624567; called by mutect2, varscan2
- CLASP1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55340014; called by muse, mutect2, varscan2
- CLCN1 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58371429; called by muse, mutect2
- CLCNKA | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs770706446, COSV58894627; called by mutect2, varscan2
- CLEC17A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.86); catalogued as rs764808677, COSV60426617; called by mutect2, varscan2
- CLMN | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54188265; called by muse, mutect2, varscan2
- CLMN | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV54188273; called by muse, mutect2, varscan2
- CLMN | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV54188287; called by muse, mutect2, varscan2
- CMYA5 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374313124, COSV71409406; called by mutect2, varscan2
- CNGA1 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV62056857; called by muse, varscan2
- CNKSR1 | c.1213G>A p.D405N (on ENST00000374253 / NM_001297647.2; = p.D398N on NM_006314.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs762074036, COSV64164187; called by muse, mutect2, varscan2
- CNTN3 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV55183979; called by mutect2, varscan2
- CNTN4 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61880939; called by muse, mutect2, varscan2
- COL11A1 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV62196924; called by muse, mutect2, varscan2
- COL15A1 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66641226, COSV66645365; called by muse, mutect2, varscan2
- COL16A1 | c.4253C>T p.S1418L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs368047384; called by mutect2, varscan2
- COL1A1 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56809362; called by muse, mutect2, varscan2
- COL23A1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV66798449; called by muse, mutect2, varscan2
- COL28A1 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV68084587; called by muse, mutect2
- COL3A1 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58596250; called by muse, mutect2, varscan2
- COL3A1 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58596263; called by muse, mutect2, varscan2
- COL4A3 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866653520, COSV67414184; called by muse, mutect2, varscan2
- COL5A2 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66415095; called by muse, varscan2
- COL5A2 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880760, COSV66415100; called by muse, mutect2
- COL6A6 | c.1857G>A p.M619I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV62037091; called by mutect2, varscan2
- COL6A6 | c.3164G>A p.G1055E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.726); catalogued as rs1177711569, COSV62037109; called by muse, mutect2
- COL6A6 | c.4193G>A p.G1398E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62037133; called by muse, mutect2, varscan2
- COL6A6 | c.4436G>A p.G1479E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62022496; called by muse, mutect2, varscan2
- COL7A1 | c.4744C>T p.P1582S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs146418495; called by muse, mutect2, varscan2
- COL8A1 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53742434; called by muse, mutect2, varscan2
- COLGALT2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV62300640; called by muse, mutect2, varscan2
- COQ3 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV54642011; called by muse, mutect2, varscan2
- CP | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV52828862, COSV52833978; called by muse, mutect2, varscan2
- CPAMD8 | c.4591G>A p.D1531N (on ENST00000651564; = p.D1484N on NM_015692.5) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs780496652, COSV71597374; called by muse, mutect2, varscan2
- CPED1 | c.617-1G>A p.X206_splice | Splice Site (SNP) | VAF 12/76 reads (16%) | catalogued as COSV60007892; called by muse, mutect2, varscan2
- CPXM1 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs267605866, COSV66045164; called by muse, mutect2, varscan2
- CREB3L3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs1167393728, COSV50266630; called by mutect2, varscan2
- CRHBP | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868589311, COSV57189956; called by mutect2, varscan2
- CRYBB2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775525695, COSV101236747; called by muse, mutect2, varscan2
- CRYBB2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV68005768; called by muse, mutect2, varscan2
- CSF1R | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV53842909; called by muse, mutect2, varscan2
- CSF2RA | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 78/520 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs758063598, COSV62624165; called by mutect2, varscan2
- CSF2RB | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs146598061; called by muse, mutect2, varscan2
- CSF3R | c.2034G>A p.M678I | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV58970772; called by muse, mutect2, varscan2
- CSF3R | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV58971818; called by muse, mutect2, varscan2
- CSMD1 | c.9977G>A p.G3326E (on ENST00000520002; = p.G3325E on NM_033225.6) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59286808; called by muse, mutect2, varscan2
- CSMD1 | c.7502C>T p.S2501F (on ENST00000520002; = p.S2500F on NM_033225.6) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1287314611, COSV59381501; called by muse, mutect2, varscan2
- CSMD2 | c.9830C>T p.S3277F | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53935568; called by muse, mutect2, varscan2
- CSMD3 | c.8146G>A p.E2716K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV52184375; called by mutect2, varscan2
- CSNK1A1L | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs775219612, COSV65789844; called by mutect2, varscan2
- CTAGE1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV66943914; called by muse, mutect2, varscan2
- CTNNA2 | c.2855C>T p.S952F (on ENST00000402739 / NM_001282597.3; = p.S904F on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1399881244, COSV58179741; called by muse, mutect2
- CTNND2 | c.2670A>T p.K890N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58926800; called by mutect2, varscan2
- CUBN | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64720657; called by muse, mutect2, varscan2
- CUX2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376228775, COSV55633068; called by muse, mutect2, varscan2
- CYP11B1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV52830232; called by muse, varscan2
- CYP19A1 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317925758, COSV53062307; called by muse, varscan2
- CYP2C19 | c.921A>C p.R307S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV64909397; called by muse, varscan2
- CYP2C9 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1348015326, COSV53252765; called by mutect2, varscan2
- CYP4A11 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 118/367 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV60225598; called by muse, mutect2, varscan2
- CYP4F12 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV61176591; called by muse, mutect2, varscan2
- CYTH2 | c.1051C>T p.H351Y (on ENST00000427476; = p.H350Y on NM_004228.7) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57310747; called by muse, varscan2
- CYYR1 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs780677251, COSV54837788; called by muse, varscan2
- CZIB | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs759745122, COSV53760351; called by mutect2, varscan2
- DAGLA | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV57199598; called by muse, mutect2, varscan2
- DAPK2 | c.497A>C p.H166P | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56048272; called by muse, varscan2
- DCBLD2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58793090; called by mutect2, varscan2
- DCLK1 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746085515, COSV55176250; called by mutect2, varscan2
- DCSTAMP | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV52578313; called by muse, mutect2, varscan2
- DDI2 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs1027637294, COSV60779198; called by muse, mutect2, varscan2
- DDX60L | c.2909T>A p.I970K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV52721680; called by muse, mutect2, varscan2
- DEFB125 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs757216800, COSV66703620; called by mutect2, varscan2
- DENND3 | c.3184C>T p.H1062Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52806744; called by muse, mutect2, varscan2
- DGKI | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV55974926; called by muse, mutect2, varscan2
- DICER1 | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as COSV58628013; called by muse, mutect2, varscan2
- DIO3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs1321177166, COSV63774593; called by mutect2, varscan2
- DLC1 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1187901231, COSV52327279; called by muse, mutect2, varscan2
- DMBT1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV57561224; called by muse, varscan2
- DMRT2 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs759064574, COSV52403636; called by muse, mutect2, varscan2
- DMRT2 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52403659; called by muse, mutect2, varscan2
- DMXL2 | c.6151C>T p.L2051F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1306216176, COSV51855960; called by muse, mutect2, varscan2
- DNAH1 | c.8242G>A p.E2748K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs750542278, COSV70236095; called by muse, mutect2, varscan2
- DNAH11 | c.8018C>T p.P2673L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV60965883; called by muse, mutect2, varscan2
- DNAH2 | c.10882G>A p.D3628N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1467502259, COSV66727034; called by muse, mutect2, varscan2
- DNAH5 | c.13454T>A p.F4485Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54251152; called by muse, mutect2, varscan2
- DNAH7 | c.8410G>A p.D2804N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56785391; called by mutect2, varscan2
- DNAH7 | c.7031G>A p.G2344E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765593; called by muse, mutect2, varscan2
- DNAH7 | c.5650C>T p.R1884* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as rs201461887; called by muse, varscan2
- DNAH9 | c.3594G>A p.W1198* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs747252427, COSV52358768; called by muse, mutect2, varscan2
- DNAH9 | c.4808G>A p.R1603Q | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761654782, COSV52351601; called by muse, mutect2, varscan2
- DNAH9 | c.7779G>A p.M2593I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52376239; called by mutect2, varscan2
- DNAI1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54284633; called by muse, mutect2, varscan2
- DNAJB6 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1412871114, COSV51095770; called by muse, mutect2, varscan2
- DNAJC16 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65448583; called by mutect2, varscan2
- DOCK2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV56956026; called by muse, mutect2, varscan2
- DOCK3 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV56541626; called by mutect2, varscan2
- DOCK6 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV53922321; called by muse, mutect2, varscan2
- DOCK7 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs1417203749, COSV52020756; called by muse, mutect2, varscan2
- DPPA4 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59512421; called by mutect2, varscan2
- DPT | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV63189910; called by muse, mutect2, varscan2
- DSCAM | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV68035877; called by muse, mutect2, varscan2
- DSCAM | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs267606133, COSV68025194; called by mutect2, varscan2
- DSG4 | c.2389C>T p.R797* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as rs1277682156, COSV57397569; called by mutect2, varscan2
- DSP | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs141805096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.5477A>T p.K1826M | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65795889; called by mutect2, varscan2
- DYNC1H1 | c.5955T>A p.H1985Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV64142291; called by muse, varscan2
- DYNC1LI2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.792); catalogued as rs1414372878, COSV99263280; called by muse, mutect2, varscan2
- DYNLRB2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs751931828, COSV58416178; called by mutect2, varscan2
- DYSF | c.4638G>A p.K1546= | Splice Region (SNP) | VAF 40/246 reads (16%) | catalogued as COSV50369369; called by muse, mutect2, varscan2
- DYTN | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.778); catalogued as rs1476740060, COSV71752247, COSV71753007; called by mutect2, varscan2
- DYTN | c.29A>T p.N10I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV71753009; called by muse, mutect2, varscan2
- E2F8 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV51466144; called by muse, varscan2
- EDA2R | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV53632953; called by muse, varscan2
- EEF2K | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777957758, COSV53781193; called by mutect2, varscan2
- EFHB | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55553495; called by muse, mutect2, varscan2
- EFL1 | c.2222C>T p.T741I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV51609865; called by muse, varscan2
- EFNB3 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56834859; called by muse, varscan2
- EIF3L | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs767371369, COSV67739671; called by mutect2, varscan2
- EIF4G1 | c.2656G>A p.E886K (on ENST00000346169 / NM_198241.3; = p.E691K on NM_004953.5) | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV59993774; called by muse, varscan2
- ELAPOR1 | c.2987G>A p.G996E | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV64041282; called by muse, mutect2, varscan2
- ELAVL2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs867331367, COSV56356901; called by mutect2, varscan2
- EMB | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as rs375679309; called by mutect2, varscan2
- EMC7 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV56629215; called by muse, varscan2
- EMILIN2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs376887473; called by mutect2, varscan2
- ENTPD1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV64602735; called by muse, mutect2, varscan2
- ENTPD3 | c.1208G>A p.W403* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV57196313; called by muse, varscan2
- EP400 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as rs1294818733, COSV57786107; called by muse, mutect2, varscan2
- EPAS1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55384341; called by muse, mutect2
- EPHA3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60695708; called by mutect2, varscan2
- EPHA6 | c.2651C>T p.S884F (on ENST00000389672 / NM_001080448.3; = p.S276F on NM_173655.4) | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67593422; called by muse, varscan2
- EPHB1 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67671252; called by mutect2, varscan2
- EPHB2 | c.2088G>A p.M696I (on ENST00000400191 / NM_001309193.2; = p.M697I on NM_004442.7) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV65866659; called by mutect2, varscan2
- EPRS1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs200738924, COSV65101513; called by muse, mutect2, varscan2
- EPS8L2 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59347567, COSV59350176; called by mutect2, varscan2
- ERC2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55662604; called by muse, mutect2, varscan2
- ERICH3 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV58612134, COSV58612762; called by muse, mutect2, varscan2
- ESR2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs145278854; called by mutect2, varscan2
- ESYT3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679808; called by muse, mutect2, varscan2
- ETS1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV60093815; called by mutect2, varscan2
- EXPH5 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV56208069; called by muse, mutect2, varscan2
- F13B | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs370218942; called by muse, mutect2, varscan2
- F3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV61844773, COSV61845580; called by muse, mutect2, varscan2
- F7 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as CD001490, COSV60648036; called by muse, mutect2, varscan2
- F8 | c.5401C>T p.P1801S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as CM980703, COSV64278570; called by muse, mutect2, varscan2
- F8 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV64278578; called by mutect2, varscan2
- FAM118A | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 62/235 reads (26%) | catalogued as rs189706370, COSV53419488; called by muse, mutect2, varscan2
- FAM131B | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1231345359, COSV58374340; called by muse, mutect2, varscan2
- FAM217B | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62563980; called by muse, mutect2, varscan2
- FAM221A | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61388586; called by muse, mutect2, varscan2
- FAM81A | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV55676542, COSV99893441; called by muse, mutect2, varscan2
- FAM83C | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs549811858, COSV65584431; called by muse, mutect2
- FAM83H | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV66354654; called by muse, mutect2, varscan2
- FAN1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.164); catalogued as COSV62952097; called by muse, mutect2, varscan2
- FANK1 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.006); catalogued as rs1412466007, COSV64136976; called by muse, mutect2, varscan2
- FAP | c.1969+1G>A p.X657_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as rs1283370893, COSV51867440; called by mutect2, varscan2
- FASTKD5 | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.052); catalogued as COSV53909559; called by muse, mutect2, varscan2
- FAT3 | c.2051G>A p.R684K | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV53091493, COSV53157699; called by muse, mutect2, varscan2
- FAT3 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53172444; called by muse, mutect2, varscan2
- FAT4 | c.14363G>A p.G4788E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58685383, COSV58708228; called by muse, varscan2
- FBN2 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs750642965, COSV52544585; called by mutect2, varscan2
- FBXL19 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57942294; called by muse, mutect2
- FCAR | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs201648976, COSV62029164; called by mutect2, varscan2
- FCER1A | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV63668434; called by muse, mutect2, varscan2
- FCGR2A | c.922C>T p.P308S (on ENST00000271450 / NM_001136219.3; = p.P307S on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV54840631; called by muse, mutect2, varscan2
- FCRL5 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62512252; called by mutect2, varscan2
- FES | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV61001032; called by muse, mutect2, varscan2
- FGD5 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV53251864; called by muse, mutect2, varscan2
- FGF12 | c.445G>A p.E149K (on ENST00000454309 / NM_021032.5; = p.E87K on NM_004113.6) | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167371; called by muse, varscan2
- FGF13 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.408); catalogued as COSV59550180; called by muse, varscan2
- FLG | c.6338G>A p.G2113E | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.686); catalogued as COSV64245521; called by muse, mutect2, varscan2
- FLG | c.5611G>A p.E1871K | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as rs200306924, COSV64248908; called by mutect2, varscan2
- FLG2 | c.5302G>A p.G1768R | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs1350335463, COSV66171486; called by muse, mutect2, varscan2
- FLNB | c.3025C>T p.R1009W | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs760728571, COSV55894928; called by mutect2, varscan2
- FLRT3 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54028496; called by muse, mutect2, varscan2
- FLT4 | c.2431G>A p.G811S | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV56121969; called by muse, varscan2
- FMN2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV60429719; called by muse, varscan2
- FN1 | c.3242T>G p.V1081G | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV60561953; called by muse, mutect2, varscan2
- FNDC1 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV51946214; called by muse, mutect2, varscan2
- FOSL2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs773239010, COSV53104112; called by mutect2, varscan2
- FOXA2 | c.442C>T p.P148S (on ENST00000377115 / NM_153675.3; = p.P154S on NM_021784.5) | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as rs771400505; called by muse, mutect2, varscan2
- FRAS1 | c.11125C>T p.P3709S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1220814857, COSV53646340; called by muse, mutect2, varscan2
- FREM2 | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs1198043921, COSV54852029; called by mutect2, varscan2
- FRMD3 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770440183, COSV58455289; called by mutect2, varscan2
- FRMD4B | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.214); catalogued as COSV68329694; called by muse, mutect2, varscan2
- FRMD7 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV53748744; called by muse, mutect2, varscan2
- FRMPD2 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs149092560; called by mutect2, varscan2
- FSHR | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58634736; called by muse, mutect2
- FTCD | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52429800; called by muse, mutect2, varscan2
- GABRA6 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV50893557; called by mutect2, varscan2
- GADL1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56985698; called by muse, varscan2
- GAK | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as COSV58509526; called by muse, mutect2, varscan2
- GALNT13 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV67238764; called by mutect2, varscan2
- GALNT16 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.188); catalogued as rs267604038, COSV61887994; called by mutect2, varscan2
- GARRE1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV55104052; called by muse, mutect2, varscan2
- GAS2L1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as rs755054331, COSV53331926; called by muse, varscan2
- GATA4 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV58735707; called by muse, varscan2
- GBP5 | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58594321; called by muse, mutect2, varscan2
- GCK | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1265357992, COSV67885804; called by muse, mutect2, varscan2
- GCN1 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs753525737, COSV56114634; called by mutect2, varscan2
- GCOM1 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51097826; called by muse, mutect2, varscan2
- GEMIN5 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs1456209195, COSV53564727; called by muse, mutect2, varscan2
- GFRAL | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767931022, COSV61232642; called by muse, mutect2, varscan2
- GHR | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV50110011; called by mutect2, varscan2
- GIMAP7 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV57960374; called by muse, mutect2, varscan2
- GIMAP8 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV56233804; called by muse, varscan2
- GJC3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as COSV57210870; called by muse, mutect2, varscan2
- GJD2 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV51749951; called by muse, mutect2, varscan2
- GLIS3 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs187615896, COSV60930732, COSV60935861; called by mutect2, varscan2
- GLMP | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55297571; called by muse, mutect2, varscan2
- GLYAT | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53540644; called by muse, varscan2
- GLYATL2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV54851513; called by mutect2, varscan2
- GML | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV55278268, COSV55278556; called by muse, mutect2, varscan2
- GMPR2 | c.869G>A p.G290E (on ENST00000355299 / NM_001351022.2; = p.G308E on NM_016576.5) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330503329, COSV57470636; called by muse, varscan2
- GMPS | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55811860; called by muse, mutect2, varscan2
- GOLGA5 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774532511, COSV50832463; called by mutect2, varscan2
- GOLGA7B | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199703901, COSV65429301; called by muse, mutect2, varscan2
- GOLT1A | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57644368; called by muse, varscan2
- GOT2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV55333372; called by muse, varscan2
- GPATCH8 | c.4192C>T p.H1398Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV59198335; called by muse, mutect2, varscan2
- GPR107 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61278832, COSV61282522; called by muse, mutect2, varscan2
- GPR135 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202021630, COSV101229307, COSV67749483; called by mutect2, varscan2
- GPR158 | c.2928G>A p.M976I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV66271145; called by mutect2, varscan2
- GPR158 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV66268698; called by muse, mutect2, varscan2
- GPR50 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs374353730, COSV54439920; called by mutect2, varscan2
- GPR78 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.014); catalogued as COSV101223921, COSV66762386; called by muse, mutect2, varscan2
- GRAP2 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV59997103; called by muse, mutect2, varscan2
- GRB10 | c.1439C>T p.P480L (on ENST00000398812; = p.P434L on NM_001001549.3) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs371726545; called by muse, varscan2
- GRM2 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56587389; called by muse, mutect2
- GRM8 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58867102; called by muse, mutect2, varscan2
- GTDC1 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54006396; called by muse, mutect2, varscan2
- GTSF1L | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65932863; called by muse, mutect2, varscan2
- GUCY2F | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs995111960, COSV54308474; called by mutect2, varscan2
- GYPB | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.671); catalogued as rs374629471; called by mutect2, varscan2
- GYS2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.155); catalogued as COSV53928754; called by muse, mutect2, varscan2
- H4C7 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs1019994955, COSV55100935; called by mutect2, varscan2
- HBP1 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51764145; called by muse, mutect2, varscan2
- HCFC1 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60077545; called by mutect2, varscan2
- HCLS1 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57523477; called by muse, mutect2, varscan2
- HCLS1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as rs1217062943, COSV58860174; called by muse, mutect2
- HDAC5 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV56821864; called by muse, mutect2, varscan2
- HECW1 | c.2826C>A p.N942K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV67839709; called by muse, mutect2, varscan2
- HECW2 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138652045; called by mutect2, varscan2
- HELZ | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV62380922; called by muse, mutect2, varscan2
- HELZ2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV64410475; called by muse, mutect2, varscan2
- HHIPL2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 66/533 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV58564235; called by mutect2, varscan2
- HHLA2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs367817011, COSV63316232; called by mutect2, varscan2
- HINT2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52413727, COSV52415759; called by muse, mutect2, varscan2
- HLCS | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103228, CM960836, COSV60795798; ClinVar: conflicting interpretations of pathogenicity; called by mutect2, varscan2
- HMBOX1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.815); catalogued as rs1374813842, COSV55071990; called by muse, varscan2
- HMCN1 | c.5449G>A p.E1817K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV54893760; called by muse, mutect2, varscan2
- HMGCR | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV55317986; called by muse, mutect2, varscan2
- HNF4G | c.499G>A p.D167N (on ENST00000354370 / NM_001330561.2; = p.D214N on NM_004133.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62973535; called by mutect2, varscan2
- HOOK3 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV56887694; called by muse, mutect2, varscan2
- HORMAD1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59273156; called by muse, mutect2, varscan2
- HPCA | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61276389; called by muse, mutect2, varscan2
- HRG | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51648241; called by muse, mutect2
- HRH1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV67955997; called by mutect2, varscan2
- HRNR | c.5648G>A p.G1883D | Missense Mutation (SNP) | VAF 92/2443 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100912823, COSV64262771; called by muse, mutect2
- HRNR | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64257734; called by muse, mutect2, varscan2
- HSCB | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53263100; called by muse, varscan2
- HSF1 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs782643377, COSV60049289; called by muse, mutect2, varscan2
- HSPB7 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1241891178, COSV61308604; called by muse, varscan2
- HSPG2 | c.11900T>A p.L3967Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60829645; called by muse, mutect2, varscan2
- HSPG2 | c.8602C>T p.P2868S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV65971184; called by muse, mutect2, varscan2
- HTR3A | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.275); catalogued as rs748387414, COSV55470950; called by muse, varscan2
- HTT | c.4170G>C p.W1390C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV61869048; called by muse, varscan2
- IDO2 | c.1210C>T p.H404Y (on ENST00000389060; = p.H417Y on NM_194294.2) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV58429554; called by mutect2, varscan2
- IFNA16 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV66510620; called by muse, mutect2, varscan2
- IGF2BP3 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1297164256, COSV51693147; called by muse, mutect2, varscan2
- IGHV3-48 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as rs566269167; called by muse, varscan2
- IGIP | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV60964638; called by mutect2, varscan2
- IGKV1-9 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1220018517; called by muse, mutect2, varscan2
- IGSF22 | c.2635G>A p.E879K (on ENST00000319338; = p.E980K on NM_173588.4) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV55011919; called by mutect2, varscan2
- IGSF9 | c.1276G>A p.E426K (on ENST00000368094 / NM_001135050.2; = p.E410K on NM_020789.4) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV63638710; called by muse, mutect2, varscan2
- IHH | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV55394040; called by muse, mutect2, varscan2
- IL15RA | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV66093191; called by muse, mutect2, varscan2
- IL16 | c.2377C>T p.R793C (on ENST00000302987 / NM_172217.5; = p.R92C on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149410949; called by mutect2, varscan2
- IL1R1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52104862; called by mutect2, varscan2
- IL22 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs745338665, COSV60160773; called by mutect2, varscan2
- IL27RA | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54603065; called by muse, mutect2
- IL4R | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.072); catalogued as rs543167942, COSV50153226; called by muse, mutect2, varscan2
- IL7R | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as rs1283489708, COSV57405726; called by mutect2, varscan2
- INHBA | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.595); catalogued as rs1371913954, COSV54225138; called by muse, mutect2, varscan2
- INO80 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV62738106; called by muse, mutect2, varscan2
- INTS13 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs187282284, COSV53905503; called by mutect2, varscan2
- INTS2 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52156557; called by mutect2, varscan2
- IPCEF1 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV54551378; called by muse, mutect2, varscan2
- IQCA1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs776730195, COSV54496991; called by mutect2, varscan2
- IRAK1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs376117072, COSV57656833; called by muse, mutect2, varscan2
- IREB2 | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51926712; called by mutect2, varscan2
- ISM1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV52608158; called by muse, mutect2, varscan2
- ISYNA1 | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | catalogued as rs1264903280, COSV54212373; called by muse, varscan2
- ITFG2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1555082532, COSV57390702; called by mutect2, varscan2
- ITGA10 | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs1553748920, COSV65199175; called by muse, mutect2, varscan2
- ITGAD | c.1084-1G>A p.X362_splice | Splice Site (SNP) | VAF 26/99 reads (26%) | catalogued as COSV66760130; called by muse, mutect2, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- ITIH1 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV56258422; called by muse, mutect2, varscan2
- ITIH5 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as COSV53673545; called by muse, mutect2, varscan2
- IVL | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs988087140, COSV64217080; called by muse, mutect2
- JAG1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54762669; called by muse, mutect2, varscan2
- JAK3 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); catalogued as COSV71687654; called by muse, varscan2
- KANK4 | c.2300C>T p.T767I | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV58094083; called by muse, mutect2, varscan2
- KANSL3 | c.2629C>T p.P877S (on ENST00000666923 / NM_001349262.2; = p.P851S on NM_001115016.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.098); catalogued as COSV62622820; called by muse, mutect2, varscan2
- KAT14 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs373399876; called by muse, mutect2, varscan2
- KCNA1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV66838148, COSV66838654; called by mutect2, varscan2
- KCNA6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs866418364, COSV54974491; called by muse, varscan2
- KCNAB1 | c.584C>T p.S195F (on ENST00000490337 / NM_172160.3; = p.S184F on NM_003471.3) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56753737; called by muse, mutect2, varscan2
- KCNB1 | c.1891G>A p.G631S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.079); catalogued as rs1433173706, COSV65570775; called by muse, mutect2, varscan2
- KCNB1 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV65566630; called by muse, varscan2
- KCNB1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65570783; called by muse, mutect2, varscan2
- KCND2 | c.1170T>A p.C390* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV58603183; called by mutect2, varscan2
- KCNG4 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs866385817, COSV57583343; called by mutect2, varscan2
- KCNH2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs267601413, COSV51126280; called by mutect2, varscan2
- KCNH7 | c.2482C>T p.L828F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59813329; called by muse, mutect2, varscan2
- KCNJ1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV60661810; called by mutect2, varscan2
- KCNJ16 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV52257233; called by muse, mutect2, varscan2
- KCNK18 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV57973241; called by mutect2, varscan2
- KCNQ1 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 109/668 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50104336, COSV50129866; called by muse, mutect2, varscan2
- KCNQ2 | c.1448G>A p.S483N (on ENST00000359125 / NM_172107.4; = p.S455N on NM_004518.6) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as COSV60553987; called by muse, mutect2, varscan2
- KCNQ3 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.388); catalogued as COSV66481546; called by muse, mutect2, varscan2
- KCNT2 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV54108132; called by muse, mutect2
- KCTD7 | c.315-1G>A p.X105_splice | Splice Site (SNP) | VAF 35/134 reads (26%) | catalogued as COSV51877671; called by muse, mutect2, varscan2
- KDM6A | c.3319C>T p.P1107S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760394554, COSV65045545; called by muse, mutect2, varscan2
- KIAA0895L | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99220404; called by mutect2, varscan2
- KIAA1109 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.125); catalogued as COSV52691661; called by muse, mutect2, varscan2
- KIAA1217 | c.3034G>A p.G1012S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV56814180, COSV56818203; called by muse, mutect2, varscan2
- KIF1B | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV55815865; called by muse, varscan2
- KIF1B | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV55804060; called by muse, varscan2
- KIRREL2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as rs781353593; called by mutect2, varscan2
- KIRREL2 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52880023, COSV99383964; called by muse, varscan2
- KLHL1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1175313582, COSV64783637; called by muse, mutect2, varscan2
- KLHL13 | c.1690C>T p.L564F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.82); catalogued as COSV53252770; called by muse, mutect2, varscan2
- KLK7 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866275891, COSV58344999; called by muse, mutect2, varscan2
- KRIT1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); catalogued as COSV60670494; called by mutect2, varscan2
- KRT2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59012648; called by muse, mutect2, varscan2
- KRT39 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374607946; called by muse, mutect2, varscan2
- KRT5 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52858983, COSV52859067; called by muse, mutect2, varscan2
- KRT5 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753298083, COSV52859004; called by mutect2, varscan2
- KRT7 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as COSV57767434; called by muse, mutect2, varscan2
- KRTAP10-1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV59979573; called by mutect2, varscan2
- KRTAP4-12 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs745512902, COSV67457681, COSV67457863, COSV67458297; called by muse, mutect2, varscan2
- KRTAP5-10 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV64796068; called by muse, varscan2
- KRTAP5-5 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 34/184 reads (18%) | PolyPhen probably damaging (0.915); catalogued as COSV68785763; called by muse, varscan2
- KXD1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.499); catalogued as rs757644789, COSV55890498; called by muse, varscan2
- KXD1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as rs990560009, COSV55890507; called by mutect2, varscan2
- L3MBTL1 | c.1864C>T p.P622S (on ENST00000418998 / NM_001377303.1; = p.P532S on NM_015478.7) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs376467003, COSV64229656; called by muse, varscan2
- LAD1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as rs777633564, COSV66213311; called by muse, mutect2, varscan2
- LAMA1 | c.5282T>G p.L1761R | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67544248; called by muse, mutect2, varscan2
- LAMA1 | c.4364C>T p.P1455L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544252; called by muse, mutect2
- LAMA3 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV58079993; called by muse, varscan2
- LARS2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs755313380, COSV55532007; called by mutect2, varscan2
- LBP | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as COSV54143649; called by muse, mutect2, varscan2
- LCE2C | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.484); catalogued as rs1011692164, COSV64228716; called by muse, mutect2, varscan2
- LCK | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60742662; called by muse, mutect2, varscan2
- LGR5 | c.997C>T p.L333= | Splice Region (SNP) | VAF 116/328 reads (35%) | catalogued as COSV57009901; called by muse, mutect2, varscan2
- LIMCH1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs146838350; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53285875; called by muse, mutect2
- LIPC | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200613217; called by mutect2, varscan2
- LIPJ | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV64245845; called by mutect2, varscan2
- LIPT1 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774872860, COSV60740452; called by muse, mutect2, varscan2
- LLGL2 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); catalogued as COSV51403050; called by muse, mutect2, varscan2
- LMNB2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57590747; called by muse, mutect2, varscan2
- LONRF3 | c.2197C>T p.P733S (on ENST00000371628 / NM_001031855.3; = p.P692S on NM_024778.5) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV59156834; called by muse, mutect2, varscan2
- LPIN1 | c.1149G>T p.R383S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV56770514; called by mutect2, varscan2
- LRG1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs765306791, COSV56705348; called by mutect2, varscan2
- LRP1 | c.9499C>T p.H3167Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.212); catalogued as COSV54525514; called by muse, mutect2, varscan2
- LRP1B | c.11335C>T p.L3779F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs1465686452, COSV67256606, COSV67273419; called by muse, mutect2, varscan2
- LRP1B | c.10087C>T p.Q3363* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV67273422; called by mutect2, varscan2
- LRP1B | c.7878T>C p.N2626= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs199852537, COSV67273424; called by muse, varscan2
- LRP2 | c.12044G>A p.G4015E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV55573638; called by muse, mutect2, varscan2
- LRP2 | c.11317C>T p.P3773S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs377050267, COSV55551382; called by muse, mutect2, varscan2
- LRRC32 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV52635423; called by muse, mutect2, varscan2
- LRRC49 | c.1533G>A p.W511* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV53015393; called by muse, mutect2, varscan2
- LRRC61 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV56232117; called by muse, mutect2, varscan2
- LRRN1 | c.1362A>T p.E454D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV60014232, COSV60016199; called by muse, mutect2, varscan2
- LUM | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57129152; called by muse, mutect2, varscan2
- LY75 | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55112771; called by muse, mutect2, varscan2
- LYZL4 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV55104279; called by muse, mutect2, varscan2
- MACC1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60546336; called by muse, mutect2, varscan2
- MACF1 | c.18676C>T p.Q6226* (on ENST00000372915; = p.Q4271* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV57143491; called by muse, varscan2
- MAGEA10 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV54885824; called by muse, mutect2, varscan2
- MAGEB6 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1413833390, COSV66872246; called by muse, mutect2
- MAGI1 | c.3617G>A p.G1206D (on ENST00000402939 / NM_001033057.2; = p.G1235D on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58344167; called by muse, mutect2, varscan2
- MAK | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV57567713; called by muse, mutect2, varscan2
- MAP3K19 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs923492725, COSV59637460; called by mutect2, varscan2
- MAP3K19 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV59642180; called by muse, mutect2, varscan2
- MAP3K20 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs376397839; called by mutect2, varscan2
- MAPK13 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs753950475, COSV52985017; called by mutect2, varscan2
- MARCHF11 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs781465967, COSV100198122, COSV60125763; called by mutect2, varscan2
- MARCHF7 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 103/431 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370056939; called by muse, mutect2, varscan2
- MAST2 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.049); catalogued as COSV63620333, COSV63621411; called by muse, varscan2
- MB | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs145465287; called by mutect2, varscan2
- MBD5 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.07); catalogued as COSV68698906; called by muse, varscan2
- MBL2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as rs1438807395, COSV64759379; called by muse, mutect2, varscan2
- MCCC2 | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV60156849; called by mutect2, varscan2
- MCM3AP | c.3700C>T p.Q1234* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV52445457; called by muse, mutect2, varscan2
- MCTP1 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56532824; called by muse, mutect2, varscan2
- MCTP2 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV59150176; called by muse, mutect2, varscan2
- MECOM | c.692C>T p.S231F (on ENST00000468789 / NM_001105078.4; = p.S419F on NM_004991.4) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449004579, COSV52960269; called by muse, mutect2, varscan2
- MED15 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV53027381; called by muse, mutect2, varscan2
- MEGF6 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1240300535, COSV53895784; called by muse, mutect2, varscan2
- MEN1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1448041546, COSV53648395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEP1B | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as rs201834412, COSV52495894; called by mutect2, varscan2
- MET | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59268880; called by muse, mutect2, varscan2
- METTL4 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771372586, COSV60603959, COSV60604530; called by mutect2, varscan2
- METTL4 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60604880; called by mutect2, varscan2
- MFF | c.374G>T p.R125I | Missense Mutation (SNP) | VAF 128/914 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58826753; called by mutect2, varscan2
- MGA | c.7817C>T p.T2606I (on ENST00000219905 / NM_001164273.1; = p.T2397I on NM_001080541.2) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54962764; called by muse, varscan2
- MGAM | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs1478782787, COSV72075819; called by muse, mutect2, varscan2
- MGAM | c.5291G>A p.G1764E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV72075820; called by mutect2, varscan2
- MGAT4C | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV59837661; called by mutect2, varscan2
- MGME1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV66624804; called by muse, mutect2, varscan2
- MIA2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV54501317; called by mutect2, varscan2
- MIB2 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV61543457; called by muse, mutect2, varscan2
- MID2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53314121, COSV99464193; called by muse, mutect2
- MINDY4 | c.558C>A p.H186Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54678252; called by muse, varscan2
- MINDY4 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1293204694, COSV54678261; called by muse, varscan2
- MINK1 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs544525710, COSV53420098; called by muse, mutect2, varscan2
- MKKS | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61399716; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by mutect2, varscan2
- MKRN3 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747181983, COSV58808804; called by muse, mutect2, varscan2
- MKS1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV56596163; called by muse, mutect2, varscan2
- MLYCD | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1039004103, COSV52306680; called by muse, mutect2, varscan2
- MME | c.1915-1G>A p.X639_splice | Splice Site (SNP) | VAF 14/75 reads (19%) | catalogued as COSV64710727; called by muse, mutect2, varscan2
- MMP27 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52782708; called by muse, mutect2, varscan2
- MMP7 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs780288531, COSV52773155; called by muse, mutect2, varscan2
- MMRN1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs751806264, COSV53337747; called by muse, mutect2, varscan2
- MMUT | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs866763981, COSV51283179; called by muse, mutect2, varscan2
- MN1 | c.3635G>A p.S1212N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.068); catalogued as COSV56561955; called by muse, varscan2
- MOB3B | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV51789988; called by muse, mutect2, varscan2
- MPG | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs566736218; called by mutect2, varscan2
- MRE11 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.907); catalogued as COSV60580247; called by muse, mutect2, varscan2
- MRPL37 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV60321442; called by muse, mutect2, varscan2
- MS4A6A | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV60617651; called by muse, mutect2, varscan2
- MSR1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV50534475; called by muse, mutect2, varscan2
- MSX1 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV66947895; called by muse, mutect2, varscan2
- MTARC1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as rs368618441, COSV65056277; called by mutect2, varscan2
- MTBP | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV59966423; called by muse, mutect2, varscan2
- MTPAP | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV53936053; called by muse, mutect2, varscan2
- MUC13 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV60701244; called by muse, mutect2, varscan2
- MUC15 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV55557137; called by muse, mutect2, varscan2
- MUC16 | c.31690G>A p.E10564K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV67492511; called by muse, mutect2, varscan2
- MUC16 | c.22082G>A p.R7361K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.083); catalogued as COSV67492532; called by mutect2, varscan2
- MUC16 | c.21373C>T p.P7125S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.1); catalogued as rs1198237117, COSV67457317; called by muse, mutect2, varscan2
- MUC16 | c.14821C>T p.P4941S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.112); catalogued as rs765374250, COSV67443915, COSV67492554; called by muse, mutect2, varscan2
- MUC16 | c.11017C>T p.P3673S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs369653663, COSV67492569; called by muse, mutect2, varscan2
- MUC16 | c.10772C>T p.S3591F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV67488870, COSV67492576; called by muse, mutect2, varscan2
- MUC16 | c.5684C>T p.S1895F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV67482126; called by muse, mutect2, varscan2
- MUC16 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as rs533548881, COSV67444798; called by muse, mutect2, varscan2
- MUC17 | c.6776C>T p.S2259L | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1355670074, COSV60286083; called by muse, varscan2
- MUC17 | c.8567G>A p.G2856D | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs773965943, COSV60302883; called by muse, mutect2, varscan2
- MUC17 | c.10318C>T p.P3440S | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.713); catalogued as COSV60302896; called by muse, varscan2
- MUC4 | c.13754G>A p.W4585* (on ENST00000463781 / NM_018406.7; = p.W349* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57802498; called by muse, mutect2, varscan2
- MXRA5 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs764313552, COSV54250014; called by muse, mutect2, varscan2
- MYBPC1 | c.3085G>A p.D1029N (on ENST00000550270 / NM_206820.2; = p.D1036N on NM_002465.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs1375319461, COSV62253226; called by muse, mutect2, varscan2
- MYBPH | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55144200; called by muse, mutect2
- MYF5 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as COSV57355344, COSV57356561; called by muse, mutect2, varscan2
- MYH1 | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs865843673, COSV56856887; called by muse, mutect2, varscan2
- MYH4 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV55118243; called by muse, mutect2, varscan2
- MYH7 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV62523625; called by muse, varscan2
- MYH7 | c.4170G>A p.K1390= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as COSV62523641; called by muse, mutect2, varscan2
- MYH8 | c.537C>T p.I179= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV67971628; called by mutect2, varscan2
- MYLK3 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV67366345; called by muse, mutect2, varscan2
- MYO18B | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs761725266, COSV59128145, COSV59148200; called by muse, varscan2
- MYO3A | c.294G>C p.L98F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.305); catalogued as COSV56348895; called by muse, mutect2, varscan2
- MYOM2 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs765956195; called by muse, mutect2, varscan2
- NAP1L4 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 39/549 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV65882237; called by muse, mutect2
- NAT2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1490596479, COSV54063161; called by muse, mutect2, varscan2
- NAV2 | c.7061C>T p.S2354L (on ENST00000396087 / NM_001244963.2; = p.S2295L on NM_145117.5) | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs753133443, COSV60659569; called by muse, mutect2, varscan2
- NAV3 | c.6230C>T p.S2077F (on ENST00000397909 / NM_001024383.2; = p.S2055F on NM_014903.6) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs779055385, COSV57101313; called by muse, mutect2, varscan2
- NBEAL1 | c.7891C>T p.H2631Y | Missense Mutation (SNP) | VAF 221/1020 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV68917255; called by muse, mutect2, varscan2
- NCEH1 | c.389C>T p.P130L (on ENST00000538775; = p.P98L on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1337587456, COSV56438009; called by muse, mutect2, varscan2
- NCKAP1 | c.2860-1G>A p.X954_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as COSV62943506; called by muse, mutect2, varscan2
- NCKAP5 | c.3407G>A p.S1136N | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58474391; called by muse, mutect2, varscan2
- NCMAP | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764863649, COSV65557646; called by muse, varscan2
- NCOA3 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100508214, COSV59073335; called by muse, varscan2
- NCOA6 | c.5783C>T p.S1928F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.641); catalogued as rs866378853, COSV62867780; called by muse, mutect2
- NDRG2 | c.653G>A p.R218K (on ENST00000298687 / NM_001354570.1; = p.R204K on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV53873600; called by muse, mutect2
- NEB | c.4156G>A p.D1386N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51453467; called by muse, mutect2, varscan2
- NEB | c.1219T>C p.F407L | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.358); catalogued as COSV51452366; called by muse, mutect2, varscan2
- NEBL | c.1478A>T p.E493V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV65805691; called by muse, varscan2
- NEK10 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs770154187, COSV55364417; called by mutect2, varscan2
- NEK10 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365278073, COSV58289414; called by muse, mutect2, varscan2
- NETO1 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55007297, COSV55015181; called by muse, mutect2, varscan2
- NEXN | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV53944675; called by muse, mutect2, varscan2
- NF2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58594619; called by mutect2, varscan2
- NFIA | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64539972; called by muse, mutect2, varscan2
- NFXL1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61200739; called by muse, mutect2, varscan2
- NHLRC2 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV63749691; called by muse, mutect2, varscan2
- NIBAN1 | c.2741G>A p.G914E | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs1458303651, COSV62287636; called by muse, mutect2, varscan2
- NIBAN1 | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62284647, COSV62287583; called by muse, mutect2, varscan2
- NIPBL | c.7753G>A p.G2585R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV56942681; called by muse, mutect2, varscan2
- NLGN4Y | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368741626, COSV59299856; called by muse, mutect2, varscan2
- NLRC4 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs772722347, COSV61594149, COSV61594733; called by muse, mutect2, varscan2
- NLRP4 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56722956; called by muse, mutect2, varscan2
- NLRX1 | c.2797C>T p.L933F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370227842; called by muse, mutect2, varscan2
- NOBOX | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.685); catalogued as rs759213699, COSV56197689; called by muse, mutect2, varscan2
- NOC3L | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV64930599; called by muse, mutect2, varscan2
- NPAP1 | c.1943A>G p.K648R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61510969; called by muse, mutect2, varscan2
- NPAS3 | c.561G>A p.V187= (on ENST00000356141 / NM_001164749.2; = p.V155= on NM_022123.3) | Splice Region (SNP) | VAF 10/71 reads (14%) | catalogued as COSV58111593; called by muse, mutect2, varscan2
- NPAS4 | c.2186G>A p.G729E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148679589; called by muse, varscan2
- NPAS4 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV60652784; called by muse, varscan2
- NPC1L1 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1188069621, COSV56922823; called by muse, mutect2, varscan2
- NPW | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.377); catalogued as COSV61586402; called by muse, mutect2
- NPY5R | c.1235T>A p.L412* | Nonsense Mutation (SNP) | VAF 24/170 reads (14%) | catalogued as COSV58453870; called by muse, mutect2, varscan2
- NR4A2 | c.1445G>A p.W482* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as COSV59895622; called by muse, mutect2, varscan2
- NRAP | c.3406C>T p.Q1136* (on ENST00000359988 / NM_001322945.2; = p.Q1101* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV63493862; called by mutect2, varscan2
- NRCAM | c.2843C>T p.P948L (on ENST00000379028 / NM_001371124.1; = p.P932L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1032482832, COSV61048679; called by muse, mutect2, varscan2
- NRK | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.177); catalogued as COSV54589624, COSV54606552; called by mutect2, varscan2
- NRK | c.4256C>T p.S1419F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54606567; called by muse, mutect2, varscan2
- NRP1 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.265); catalogued as rs373328655; called by mutect2, varscan2
- NRXN1 | c.2456A>T p.K819I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58491864; called by mutect2, varscan2
- NRXN2 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55462248; called by mutect2, varscan2
- NRXN3 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73587335; called by muse, mutect2, varscan2
- NT5C1B | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as rs753167200, COSV58398982; called by mutect2, varscan2
- NUAK1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs781345878, COSV54608122, COSV99777115; called by mutect2, varscan2
- NUMB | c.586C>G p.R196G (on ENST00000355058; = p.R185G on NM_003744.5) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61830387, COSV61832174; called by muse, mutect2, varscan2
- NUP210L | c.3937C>T p.H1313Y | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55157471; called by muse, mutect2, varscan2
- NWD1 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs1234059380, COSV60351395; called by muse, mutect2, varscan2
- NXPE4 | c.1483C>T p.Q495* (on ENST00000375478 / NM_001077639.2; = p.Q211* on NM_017678.3) | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV64944396; called by mutect2, varscan2
- NYAP2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV56002725; called by muse, mutect2, varscan2
- OBSCN | c.14993C>T p.S4998F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs915552522, COSV52827378; called by muse, mutect2
- OGA | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as COSV63381376; called by muse, mutect2, varscan2
- OGDHL | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV65104636; called by muse, mutect2, varscan2
- OGFOD2 | c.877C>T p.R293W (on ENST00000228922 / NM_001304833.1; = p.R233W on NM_024623.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as rs769857147, COSV54908695; called by muse, mutect2, varscan2
- OLAH | c.511G>A p.E171K (on ENST00000378228 / NM_001039702.3; = p.E224K on NM_018324.3) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1465694432, COSV65493662; called by muse, mutect2, varscan2
- OR10G8 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70909398; called by muse, varscan2
- OR10G9 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV66686830; called by muse, mutect2, varscan2
- OR10J1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.972); catalogued as COSV71128742, COSV71129218; called by muse, mutect2, varscan2
- OR10Q1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57471083; called by muse, mutect2, varscan2
- OR13C2 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV73377649; called by mutect2, varscan2
- OR14C36 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV58600456; called by muse, varscan2
- OR1J2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV58945185; called by muse, mutect2, varscan2
- OR1N2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65461170; called by muse, mutect2, varscan2
- OR2A12 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV68821412; called by muse, mutect2, varscan2
- OR2A14 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101376515, COSV68718644; called by muse, mutect2, varscan2
- OR2A25 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs776622645, COSV68717675; called by muse, varscan2
- OR2J2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs191240319, COSV65848126, COSV65848370; called by muse, mutect2, varscan2
- OR2J2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs866648498, COSV65848372; called by muse, mutect2, varscan2
- OR2J2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs868846240, COSV65848376; called by muse, mutect2, varscan2
- OR2T27 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV61281368; called by mutect2, varscan2
- OR4C46 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs777097476, COSV60219182, COSV60221186; called by muse, mutect2, varscan2
- OR4K1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV53458913, COSV53460428; called by muse, varscan2
- OR4K14 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59292858; called by muse, mutect2, varscan2
- OR4N2 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1176764184, COSV60054808; called by mutect2, varscan2
- OR51F1 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs149687850, COSV58580835; called by mutect2, varscan2
- OR51S1 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.42); catalogued as rs1254430073, COSV59060176; called by muse, mutect2, varscan2
- OR5A1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV57376909, COSV57378237; called by muse, mutect2, varscan2
- OR5K2 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as COSV71143100, COSV71143512; called by muse, mutect2, varscan2
- OR6C4 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs751253162, COSV67793301; called by muse, mutect2, varscan2
- OR6K3 | c.370G>A p.E124K (on ENST00000368146; = p.E108K on NM_001005327.2) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63746475; called by muse, mutect2, varscan2
- OR7A5 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV59234232; called by muse, mutect2, varscan2
- OR7E24 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71702356; called by muse, mutect2, varscan2
- OXCT1 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52177071; called by mutect2, varscan2
- P2RY8 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67178198; called by muse, mutect2, varscan2
- P4HA2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1450713518, COSV51324081, COSV51331379; called by muse, mutect2, varscan2
1,310 further variants in this file (559 protein-altering or splice-affecting, 699 silent, 52 other) are not listed here.
